Somatic mutation profile of tumor specimen TCGA-DD-AAEB-01A (aliquot TCGA-DD-AAEB-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.6 years (22,121 days).
Specimen TCGA-DD-AAEB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 727d105b-d7f0-4191-82be-59ad7e3db863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEB-10A (Blood Derived Normal), aliquot TCGA-DD-AAEB-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c31ade6d-d103-411d-9a4e-ec93e0b4bfbd

The open-access MAF lists 127 somatic variants for this specimen: 106 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 83, Silent 21, Frame Shift Del 7, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 3, In Frame Del 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 60/176 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- ABCA1 | c.4837A>G p.I1613V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV101036620; called by muse, mutect2, varscan2
- ABCB8 | c.718A>G p.I240V (on ENST00000297504 / NM_001282291.2; = p.I223V on NM_007188.5) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.208); catalogued as rs747183999, COSV99873951; called by muse, mutect2, varscan2
- ADAMTS13 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.164); catalogued as COSV100746985, COSV63022439; called by muse, mutect2, varscan2
- ANO1 | c.2778G>T p.E926D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100796937; called by muse, mutect2, varscan2
- AQP1 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV100310854; called by muse, mutect2, varscan2
- ARFGAP3 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as COSV54311552, COSV99605149; called by muse, mutect2, varscan2
- ATP2B2 | c.2863A>G p.I955V (on ENST00000352432; = p.I921V on NM_001683.5) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV100659744; called by muse, mutect2, varscan2
- BSN | c.4190A>G p.Y1397C | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs748088212, COSV99607478; called by muse, mutect2, varscan2
- C5 | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99797284; called by muse, mutect2, varscan2
- C8orf34 | c.1582T>A p.S528T | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100444793; called by muse, mutect2, varscan2
- CEL | c.2209G>C p.A737P (on ENST00000673714; = p.A734P on NM_001807.6) | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1429103234, COSV100672272; called by muse, mutect2, varscan2
- CGB7 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1479504138; called by muse, mutect2, varscan2
- CLTC | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99291816; called by muse, mutect2, varscan2
- COL12A1 | c.4099A>G p.I1367V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100485515; called by muse, mutect2, varscan2
- CORO1C | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99775779; called by muse, mutect2, varscan2
- CORO1C | c.747T>A p.N249K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99775781; called by muse, mutect2, varscan2
- CRIP2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100231591; called by muse, mutect2, varscan2
- CRISPLD1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100081657; called by muse, mutect2, varscan2
- CSMD3 | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52183022; called by muse, mutect2, varscan2
- CYP2C8 | c.1179del p.V394Cfs*20 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as rs774216153; called by mutect2, pindel, varscan2
- DEPTOR | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV99637975; called by muse, mutect2, varscan2
- DGKD | c.196T>G p.S66A (on ENST00000264057 / NM_152879.3; = p.S22A on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99895609; called by muse, mutect2
- DNAJB12 | c.689C>T p.A230V (on ENST00000338820; = p.A196V on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs1235529625, COSV100123683; called by muse, mutect2, varscan2
- DOCK8 | c.1722C>A p.N574K | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV101209822; called by muse, mutect2, varscan2
- DPEP2 | c.1068C>A p.G356= | Splice Region (SNP) | VAF 29/58 reads (50%) | catalogued as rs1207698660, COSV99263070; called by muse, mutect2, varscan2
- EPG5 | c.4034A>G p.H1345R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs200456950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZH2 | c.2051T>G p.I684S (on ENST00000460911 / NM_001203247.2; = p.I689S on NM_004456.5) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234985; called by muse, mutect2, varscan2
- FAM222B | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100368253; called by muse, mutect2, varscan2
- FRMPD4 | c.3005T>C p.M1002T | Missense Mutation (SNP) | VAF 119/146 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV101042294; called by muse, mutect2, varscan2
- GLIPR1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs150528235, COSV99875547; called by muse, mutect2, varscan2
- GMCL1 | c.1504A>G p.I502V | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV99247565; called by muse, mutect2, varscan2
- GNL3 | c.1343T>A p.L448* | Nonsense Mutation (SNP) | VAF 69/161 reads (43%) | catalogued as COSV99803606; called by muse, mutect2, varscan2
- GPLD1 | c.794C>A p.T265K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100015089; called by muse, mutect2, varscan2
- GSTO1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100866912; called by muse, mutect2, varscan2
- HEXB | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 51/142 reads (36%) | catalogued as COSV54667173, COSV99784127; called by muse, mutect2, varscan2
- IGF2R | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100806995; called by muse, mutect2, varscan2
- IL12RB1 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101651875; called by muse, mutect2, varscan2
- IL9R | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99729373, COSV99729532; called by mutect2, varscan2
- ING3 | c.929G>C p.S310T | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV100253130; called by muse, mutect2, varscan2
- KCNH8 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 90/219 reads (41%) | catalogued as COSV100108798, COSV60475108; called by muse, mutect2, varscan2
- KMT2B | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55859506; called by muse, mutect2, varscan2
- KNG1 | c.1772T>A p.I591N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99405196; called by muse, mutect2, varscan2
- LIMK1 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV100283044; called by muse, mutect2, varscan2
- LRRIQ1 | c.3733C>T p.Q1245* | Nonsense Mutation (SNP) | VAF 38/91 reads (42%) | catalogued as COSV101279641; called by muse, mutect2, varscan2
- LRRN2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100912767; called by muse, mutect2, varscan2
- LTBP4 | c.1930C>T p.R644C (on ENST00000308370 / NM_001042544.1; = p.R607C on NM_003573.2) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1355671197, COSV99180646; called by muse, mutect2, varscan2
- MED12L | c.5317C>T p.R1773C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1307977762, COSV99851823; called by muse, mutect2, varscan2
- MGLL | c.332A>G p.Y111C (on ENST00000398104 / NM_001003794.2; = p.Y121C on NM_007283.6) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs765489619, COSV99411557; called by muse, mutect2, varscan2
- MGLL | c.71A>C p.N24T (on ENST00000398104 / NM_001003794.2; = p.N34T on NM_007283.6) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99411565, COSV99412205; called by muse, mutect2, varscan2
- MTR | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 122/190 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100855816; called by muse, mutect2, varscan2
- MYO7A | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101289057; called by muse, mutect2, varscan2
- NACA | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as rs1224854276, COSV100771116, COSV63272343; called by muse, mutect2, varscan2
- NDN | c.577A>C p.M193L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100086267; called by muse, mutect2, varscan2
- NDUFB10 | c.357T>A p.C119* | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as COSV99238717; called by muse, mutect2, varscan2
- NDUFB10 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99238723; called by muse, mutect2, varscan2
- NDUFS1 | c.1934G>T p.R645I | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99260499; called by muse, mutect2, varscan2
- NLRP12 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100144932; called by muse, mutect2, varscan2
- NPHP3 | c.2200A>G p.I734V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100446651; called by muse, mutect2, varscan2
- OBSL1 | c.3803G>T p.R1268L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.724); catalogued as COSV99216370; called by muse, mutect2, varscan2
- OR2G2 | c.685T>A p.L229M | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as COSV100189612; called by muse, mutect2, varscan2
- OR4P4 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100111594; called by muse, mutect2, varscan2
- OR5R1 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100393299; called by muse, mutect2, varscan2
- OR8U1 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100163783; called by muse, mutect2
- OTOA | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754836536, COSV53750123, COSV53757868; called by muse, mutect2, varscan2
- PAICS | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 109/250 reads (44%) | PolyPhen probably damaging (0.995); catalogued as COSV51710403; called by muse, mutect2, varscan2
- PRCP | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765431937, COSV100475724; called by muse, mutect2, varscan2
- PTPN13 | c.1490G>T p.R497I | Missense Mutation (SNP) | VAF 152/387 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364196, COSV57407463; called by muse, mutect2, varscan2
- RASA3 | c.1506C>A p.H502Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV100480015; called by muse, mutect2, varscan2
- SAMHD1 | c.406A>T p.I136F | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483833; called by muse, mutect2, varscan2
- SCD | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs772784459, COSV100948853; called by muse, mutect2, varscan2
- SEC61A1 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1226129636, COSV99684730; called by muse, mutect2, varscan2
- SEMA7A | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984575; called by muse, mutect2, varscan2
- SETD2 | c.7099-1G>T p.X2367_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | catalogued as COSV100338248; called by muse, mutect2, varscan2
- SIPA1L1 | c.974G>T p.W325L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100665217; called by muse, mutect2, varscan2
- SLA | c.521C>T p.P174L (on ENST00000338087 / NM_001045556.3; = p.P214L on NM_006748.4) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55093094; called by muse, mutect2, varscan2
- SLC26A7 | c.795+1G>T p.X265_splice | Splice Site (SNP) | VAF 46/74 reads (62%) | catalogued as COSV99402750; called by muse, mutect2, varscan2
- SLC6A12 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100675007; called by muse, mutect2, varscan2
- SMIM7 | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100701438; called by muse, mutect2, varscan2
- STIL | c.3418G>T p.E1140* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV99680641; called by mutect2, varscan2
- STYXL1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99951267; called by muse, mutect2, varscan2
- SYT1 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV99694189; called by muse, mutect2, varscan2
- TCAIM | c.1450T>C p.C484R | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703193; called by muse, mutect2, varscan2
- TMUB1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99879582; called by muse, mutect2
- TOX | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV63851368; called by muse, mutect2, varscan2
- TRAM2 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV99480008; called by muse, mutect2, varscan2
- TTN | c.54838A>G p.S18280G (on ENST00000591111; = p.S10856G on NM_003319.4) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | PolyPhen benign (0.001); catalogued as COSV100598109; called by muse, mutect2, varscan2
- USP3 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1566921687, COSV99165647; called by muse, mutect2, varscan2
- VAV3 | c.1593G>C p.Q531H | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100579256; called by muse, mutect2, varscan2
- VPS33B | c.973A>G p.N325D | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV100325469; called by muse, mutect2, varscan2
- ZAR1 | c.1273T>G p.*425Eext*13 | Nonstop Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99976078; called by muse, mutect2, varscan2
- ZMAT5 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722600; called by muse, mutect2, varscan2
- ZPLD1 | c.472C>A p.P158T (on ENST00000466937 / NM_001329788.1; = p.P174T on NM_175056.2) | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082972, COSV60355053; called by muse, mutect2, varscan2
- AKR7A2 | c.992A>C p.E331A | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, varscan2
- ASTE1 | c.919_948del p.Q307_V316del | In Frame Del (DEL) | VAF 46/144 reads (32%) | called by mutect2, varscan2
- DGKG | c.1599_1600+1del p.X533_splice | Splice Site (DEL) | VAF 12/44 reads (27%) | called by pindel, varscan2
- ELP1 | c.3132_3133dup p.L1045Rfs*41 | Frame Shift Ins (INS) | VAF 46/117 reads (39%) | called by mutect2, pindel, varscan2
- GDF2 | c.1150T>C p.F384L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HSD17B7 | c.470_488del p.L157Hfs*41 | Frame Shift Del (DEL) | VAF 135/510 reads (26%) | called by mutect2, pindel, varscan2
- ILKAP | c.590dup p.H197Qfs*3 | Frame Shift Ins (INS) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- IQCC | c.246del p.L83Cfs*21 | Frame Shift Del (DEL) | VAF 111/307 reads (36%) | called by mutect2, pindel, varscan2
- ITGA9 | c.1565del p.K522Rfs*27 | Frame Shift Del (DEL) | VAF 75/217 reads (35%) | called by mutect2, pindel, varscan2
- PAN2 | c.3149_3156del p.L1050Qfs*22 (on ENST00000425394 / NM_001127460.3; = p.L1046Qfs*22 on NM_014871.5) | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- SENP6 | c.2757del p.P920Lfs*39 | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- SLC10A1 | c.874_875dup p.Q293Sfs*28 | Frame Shift Ins (INS) | VAF 60/154 reads (39%) | called by mutect2, varscan2
- SLC12A2 | c.2976del p.E993Nfs*9 | Frame Shift Del (DEL) | VAF 226/555 reads (41%) | called by mutect2, varscan2
- ATP2B1 | c.369C>G p.G123= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99665275; called by muse, mutect2, varscan2
- BORCS7 | c.160C>A p.R54= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV100185592; called by muse, mutect2, varscan2
- CAPN13 | c.465G>A p.V155= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV99699851; called by muse, mutect2, varscan2
- DSCAML1 | c.2286C>T p.I762= (on ENST00000321322; = p.I702= on NM_020693.4) | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100354936; called by muse, mutect2, varscan2
- EGLN2 | c.273G>A p.L91= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100393659; called by muse, mutect2
- GPR162 | c.822C>T p.S274= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV50590483; called by muse, mutect2, varscan2
- HDAC1 | c.972C>A p.I324= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV100269504; called by muse, mutect2, varscan2
- INTS8 | c.1296A>T p.S432= | Silent (SNP) | VAF 180/734 reads (25%) | catalogued as COSV100569163; called by muse, varscan2
- NHLRC3 | c.357A>G p.Q119= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs917357887, COSV100612684; called by muse, mutect2, varscan2
- NNT | c.1710C>T p.N570= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV99238492; called by muse, mutect2, varscan2
- PPAT | c.1452T>C p.D484= | Silent (SNP) | VAF 104/286 reads (36%) | catalogued as COSV51704400, COSV99947099; called by muse, mutect2, varscan2
- SEMA3A | c.1591C>A p.R531= | Silent (SNP) | VAF 69/243 reads (28%) | catalogued as COSV54879339, COSV99545597; called by muse, mutect2, varscan2
- SLC25A31 | c.672C>T p.V224= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV99829277; called by muse, mutect2, varscan2
- SNX25 | c.1041A>G p.K347= | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as COSV99252452; called by muse, mutect2
- STIL | c.3417G>A p.E1139= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV99680644; called by muse, mutect2, varscan2
- TERT | c.879C>A p.R293= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99716856; called by muse, mutect2, varscan2
- TIAM1 | c.519A>T p.A173= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99733257; called by muse, mutect2, varscan2
- TRIM39 | c.654G>A p.E218= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV100935642; called by muse, mutect2, varscan2
- TRPV5 | c.2010G>A p.G670= | Silent (SNP) | VAF 63/100 reads (63%) | catalogued as COSV99520166; called by muse, mutect2, varscan2
- ZFP30 | c.1395C>T p.P465= | Silent (SNP) | VAF 55/113 reads (49%) | catalogued as rs575517303, COSV100665813; called by muse, mutect2, varscan2
- ZNF276 | c.1251C>T p.P417= (on ENST00000443381 / NM_001113525.2; = p.P342= on NM_152287.4) | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs765026468, COSV57070961, COSV57071540; called by muse, mutect2, varscan2
